Somatic mutation profile of tumor specimen 0DVJOG from CCDI case PBCMGW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.6 years (3,863 days).
Specimen 0DVJOG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ea98f98-cc31-4893-a948-2c222e88c2b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVJNO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d51262e7-fa89-4a43-b5fa-c2e22de72f68

The open-access MAF lists 7 somatic variants for this specimen: 2 protein-altering or splice-affecting, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, 3'UTR 2, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPZ | c.1261G>A p.V421I (on ENST00000360986 / NM_001014447.3; = p.V410I on NM_003652.3) | Missense Mutation (SNP) | VAF 117/372 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as rs368219391; called by muse, mutect2, varscan2
- POLG | c.2977C>T p.R993C | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs551811489, COSV99175243; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRD | c.470+27G>A | Intron (SNP) | VAF 31/78 reads (40%) | catalogued as rs368857204; called by muse, mutect2, varscan2
- MYO9B | c.4114-51C>A | Intron (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- RETN | c.*8C>A | 3'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- RNASET2 | c.-9-22G>T | Intron (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- RWDD3 | c.*93A>C | 3'UTR (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
